Somatic mutation profile of tumor specimen ALCH-B2XX-TTP1-A (aliquot ALCH-B2XX-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B2XX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 69.7 years (25,458 days).
Specimen ALCH-B2XX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a93e0533-e44e-49a0-b66f-15c233bf5201.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2XX-NB1-A (Blood Derived Normal), aliquot ALCH-B2XX-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c70a34ee-9d13-42fc-826d-62f016f6e4fb

The open-access MAF lists 257 somatic variants for this specimen: 185 protein-altering or splice-affecting, 42 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 42, Intron 15, Nonsense Mutation 14, 3'UTR 6, Splice Site 4, 5'Flank 4, RNA 2, 5'UTR 2, 3'Flank 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 32/370 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- AHNAK2 | c.13366G>A p.V4456M | Missense Mutation (SNP) | VAF 24/501 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs569348872, COSV60926415; called by muse, mutect2
- CBLC | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs747076535; called by muse, mutect2
- COL4A5 | c.3745G>T p.G1249* | Nonsense Mutation (SNP) | VAF 16/137 reads (12%) | catalogued as COSV60363782; called by mutect2, varscan2
- COL5A1 | c.5362G>T p.G1788C | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65673147; called by muse, mutect2, varscan2
- CPNE7 | c.636C>A p.N212K | Missense Mutation (SNP) | VAF 18/279 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs760161077, COSV52013206; called by muse, mutect2
- DBT | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 25/531 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs762751168, COSV100923414; called by muse, mutect2
- DDX23 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV57285839; called by muse, mutect2
- DHX38 | c.1780G>T p.A594S | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99194611; called by muse, mutect2
- DLC1 | c.77A>T p.D26V | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as rs1212051176; called by muse, mutect2
- DSCAM | c.5597C>A p.S1866* | Nonsense Mutation (SNP) | VAF 26/385 reads (7%) | catalogued as COSV68031154, COSV68038595; called by muse, mutect2
- F9 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 39/429 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM990573, CM990574; called by muse, mutect2
- FAM135B | c.2948G>C p.G983A | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as COSV99428295; called by muse, mutect2
- FAM47B | c.456G>T p.Q152H | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV61456234; called by muse, mutect2
- FANCA | c.123G>C p.Q41H | Missense Mutation (SNP) | VAF 32/592 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV101224760; called by muse, mutect2
- FAT3 | c.12451G>T p.G4151W | Missense Mutation (SNP) | VAF 20/293 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99972419; called by muse, mutect2
- FYCO1 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 34/572 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56115360; called by muse, mutect2
- GABRG3 | c.647G>A p.W216* | Nonsense Mutation (SNP) | VAF 23/415 reads (6%) | catalogued as COSV61536283; called by muse, mutect2
- HGF | c.700C>G p.R234G | Missense Mutation (SNP) | VAF 46/515 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55946077, COSV55952010; called by muse, mutect2
- HSPG2 | c.10354C>T p.R3452* | Nonsense Mutation (SNP) | VAF 7/158 reads (4%) | catalogued as rs1208167285, CM065275, COSV65934072; called by muse, mutect2
- KNTC1 | c.5153G>T p.W1718L | Missense Mutation (SNP) | VAF 13/322 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV100338030; called by muse, mutect2
- KNTC1 | c.5154G>T p.W1718C | Missense Mutation (SNP) | VAF 13/321 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100338032; called by muse, mutect2
- LPCAT1 | c.1522C>G p.P508A | Missense Mutation (SNP) | VAF 28/386 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99358836; called by muse, mutect2
- LRRIQ1 | c.528G>T p.E176D | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67814062; called by muse, mutect2, varscan2
- MKNK2 | c.750G>T p.P250= | Splice Region (SNP) | VAF 12/189 reads (6%) | catalogued as COSV51734504; called by muse, mutect2
- MMP16 | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54177856; called by muse, mutect2
- MUC16 | c.34789C>A p.H11597N | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.352); catalogued as COSV67501516; called by muse, mutect2
- MYT1L | c.2558G>T p.R853L | Missense Mutation (SNP) | VAF 24/476 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV101219097, COSV67726880; called by muse, mutect2
- NLRP3 | c.2505C>A p.C835* | Nonsense Mutation (SNP) | VAF 20/536 reads (4%) | catalogued as COSV60219210; called by muse, mutect2
- NSD2 | c.2824G>T p.G942W | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56387765, COSV56391074; called by muse, mutect2
- NYAP2 | c.1279del p.H427Mfs*20 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | catalogued as COSV55998384; called by mutect2, pindel, varscan2
- ODF3L1 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.99); catalogued as rs1260796756; called by muse, mutect2
- OLFM3 | c.473C>T p.P158L (on ENST00000338858 / NM_001288821.1; = p.P138L on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV58795523; called by muse, mutect2
- OR10T2 | c.429G>T p.L143F | Missense Mutation (SNP) | VAF 35/507 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.148); catalogued as COSV57781214; called by muse, mutect2
- PAK3 | c.1571C>G p.S524C (on ENST00000262836 / NM_001324328.2; = p.S509C on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/532 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53278648, COSV99457298; called by muse, mutect2
- PAX6 | c.635G>A p.R212K | Missense Mutation (SNP) | VAF 27/486 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as COSV99570661; called by muse, mutect2
- PCDHGA2 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53944347; called by muse, mutect2, varscan2
- PPP4R4 | c.881T>C p.L294S | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs771762895; called by muse, mutect2
- PRAMEF6 | c.1237T>C p.Y413H | Missense Mutation (SNP) | VAF 44/1033 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1334422934; called by muse, mutect2
- PXDN | c.4258G>T p.G1420C | Missense Mutation (SNP) | VAF 52/485 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1193530648; called by muse, mutect2, varscan2
- R3HCC1 | c.470C>T p.A157V (on ENST00000411463; = p.A117V on NM_001136108.3) | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1483348289; called by muse, mutect2
- RFX1 | c.1165G>T p.G389C | Missense Mutation (SNP) | VAF 31/326 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99586184; called by muse, mutect2
- RNF112 | c.1570C>A p.L524M | Missense Mutation (SNP) | VAF 14/229 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as rs776674182; called by muse, mutect2
- SGIP1 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.027); catalogued as COSV52776158; called by muse, mutect2
- SH3KBP1 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 30/648 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65641379; called by muse, mutect2
- SLC13A5 | c.608G>T p.R203M | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs949110880; called by muse, mutect2
- SPEG | c.2728C>A p.R910S | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV100404637, COSV56677547; called by muse, varscan2
- THSD7B | c.232C>A p.L78M | Missense Mutation (SNP) | VAF 21/365 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as rs751954088; called by muse, mutect2
- TTC21B | c.2167C>G p.R723G | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as rs201500142; called by muse, mutect2
- UBE2O | c.2791G>T p.V931L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as COSV60062840; called by muse, mutect2
- UTP20 | c.103G>C p.D35H | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55381863; called by muse, mutect2
- XPNPEP2 | c.1930C>T p.H644Y | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV64368437; called by muse, mutect2
- ZFHX4 | c.8744C>A p.S2915Y | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51501678; called by muse, mutect2, varscan2
- ZNF536 | c.3193C>T p.L1065F | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.125); catalogued as COSV62818520; called by muse, mutect2
- ABCD1 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2
- ACAP2 | c.1601C>A p.S534Y | Missense Mutation (SNP) | VAF 34/414 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2
- AGAP3 | c.1754T>C p.F585S (on ENST00000622464; = p.F621S on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- AMOT | c.1688C>A p.S563Y (on ENST00000371959 / NM_001113490.1; = p.S154Y on NM_133265.3) | Missense Mutation (SNP) | VAF 61/425 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANK1 | c.87G>T p.L29F | Missense Mutation (SNP) | VAF 46/584 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2
- ANKRD31 | c.2983G>C p.G995R | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.071); called by muse, mutect2
- ASTN2 | c.1248G>T p.E416D (on ENST00000313400 / NM_001365069.1; = p.E365D on NM_014010.5) | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated, low confidence (0.94); PolyPhen possibly damaging (0.899); called by muse, mutect2
- BCORL1 | c.2362G>T p.A788S | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- BMERB1 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CA10 | c.342G>T p.L114F | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.989); called by muse, mutect2
- CASR | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.095); called by muse, mutect2
- CCDC160 | c.434T>A p.L145H | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CCR10 | c.782T>G p.L261R | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CDHR3 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 33/406 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.095); called by muse, mutect2
- CERCAM | c.963+1G>T p.X321_splice | Splice Site (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
- CHD7 | c.8501G>T p.G2834V | Missense Mutation (SNP) | VAF 46/681 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2
- CHD8 | c.5327G>T p.R1776L (on ENST00000646647 / NM_001170629.2; = p.R1497L on NM_020920.4) | Missense Mutation (SNP) | VAF 36/365 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.094); called by muse, mutect2
- CLSPN | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 38/546 reads (7%) | called by muse, mutect2
- CNKSR2 | c.65-1G>T p.X22_splice | Splice Site (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- CPA6 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CSMD1 | c.10530C>G p.Y3510* (on ENST00000520002; = p.Y3509* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 13/128 reads (10%) | called by muse, mutect2
- CSMD3 | c.3421C>A p.L1141I (on ENST00000297405 / NM_001363185.1; = p.L1037I on NM_052900.3) | Missense Mutation (SNP) | VAF 20/397 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); called by muse, mutect2
- CTXN2 | c.71C>A p.T24N | Missense Mutation (SNP) | VAF 36/443 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); called by muse, mutect2
- DCDC1 | c.5030G>T p.R1677I (on ENST00000597505 / NM_001367979.1; = p.R784I on NM_020869.3) | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); called by muse, mutect2
- DCSTAMP | c.1235T>C p.V412A | Missense Mutation (SNP) | VAF 28/477 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.038); called by muse, mutect2
- DEFB119 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.305); called by muse, mutect2
- DNAJC25 | c.942G>T p.W314C | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DOK6 | c.292C>A p.L98M | Missense Mutation (SNP) | VAF 37/530 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- DTNA | c.957G>C p.M319I | Missense Mutation (SNP) | VAF 53/700 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2
- DUOX2 | c.1598A>G p.E533G | Missense Mutation (SNP) | VAF 38/704 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2
- EIF4G2 | c.1245G>T p.M415I | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- ELF2 | c.341C>T p.S114L (on ENST00000379550 / NM_001331036.2; = p.S54L on NM_006874.4) | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2
- ERCC6L | c.984G>C p.R328S | Missense Mutation (SNP) | VAF 20/283 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ETNPPL | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- FAM184A | c.1526A>G p.Q509R | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.469); called by muse, mutect2
- FAM47C | c.2800G>T p.V934L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); called by muse, mutect2
- FAT1 | c.6991G>A p.D2331N | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.065); called by muse, mutect2
- FMR1 | c.1752C>A p.C584* | Nonsense Mutation (SNP) | VAF 22/376 reads (6%) | called by muse, mutect2
- FREM2 | c.1069T>G p.F357V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- FRMD4A | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FRRS1L | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GAA | c.1988A>T p.Q663L | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GAD1 | c.337A>T p.T113S | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, mutect2
- GATAD2B | c.601C>G p.P201A | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- GLUD2 | c.1270G>T p.V424F | Missense Mutation (SNP) | VAF 56/684 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2
- GMCL2 | c.74C>A p.A25D | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.185); called by muse, mutect2
- GPR75 | c.1268C>A p.S423Y | Missense Mutation (SNP) | VAF 23/318 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HAUS7 | c.261G>T p.W87C | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HAUS7 | c.260G>A p.W87* | Nonsense Mutation (SNP) | VAF 24/302 reads (8%) | called by muse, mutect2
- HERC1 | c.2695G>T p.V899L | Missense Mutation (SNP) | VAF 31/313 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- HSPG2 | c.887A>T p.H296L | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, mutect2
- IGSF1 | c.3253C>A p.L1085I | Missense Mutation (SNP) | VAF 48/450 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- IMPA1 | c.365T>G p.V122G | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IQGAP2 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- JAK3 | c.1833T>A p.Y611* | Nonsense Mutation (SNP) | VAF 17/399 reads (4%) | called by muse, mutect2
- JMJD1C | c.2225C>A p.S742Y | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- KBTBD7 | c.635A>T p.E212V | Missense Mutation (SNP) | VAF 44/704 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2
- KCNH1 | c.1669C>A p.Q557K (on ENST00000271751 / NM_172362.3; = p.Q530K on NM_002238.4) | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2
- KDR | c.1987+2T>A p.X663_splice | Splice Site (SNP) | VAF 25/306 reads (8%) | called by muse, mutect2
- KIAA1210 | c.1146C>A p.S382R | Missense Mutation (SNP) | VAF 25/285 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- KIR3DL3 | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2
- KLHL4 | c.1905G>T p.R635S | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.199); called by muse, mutect2
- KLK2 | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2
- LSS | c.2047C>A p.P683T | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2
- MCF2L2 | c.2900A>C p.Q967P | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.348); called by muse, mutect2
- MECR | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 24/421 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.046); called by muse, mutect2
- MECR | c.145G>T p.G49W | Missense Mutation (SNP) | VAF 25/427 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2
- MID2 | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MMP16 | c.1387A>T p.S463C | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2
- NECTIN1 | c.979G>T p.G327C | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NLRP2 | c.113A>T p.E38V | Missense Mutation (SNP) | VAF 42/586 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.096); called by muse, mutect2
- NLRP8 | c.1547C>A p.A516D | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOD1 | c.1509G>C p.E503D | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OBSCN | c.9809C>T p.T3270I | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- OR11G2 | c.143C>A p.T48N | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.374); called by muse, mutect2
- OR1G1 | c.108G>T p.L36F | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- OR2K2 | c.209G>T p.G70V (on ENST00000374428; = p.G41V on NM_205859.2) | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2M4 | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2
- OR52N2 | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 50/506 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.033); called by muse, mutect2
- OR8B2 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); called by muse, mutect2
- OR8K3 | c.850T>A p.L284M | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- ORC4 | c.73C>A p.R25S | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OTOG | c.6196C>A p.L2066M | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.084); called by muse, mutect2
- OTX2 | c.460C>T p.P154S (on ENST00000408990 / NM_172337.3; = p.P162S on NM_021728.4) | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB13 | c.711C>A p.N237K | Missense Mutation (SNP) | VAF 66/690 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCLO | c.15355C>G p.L5119V | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PEX1 | c.2956C>G p.P986A | Missense Mutation (SNP) | VAF 48/560 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PGAP4 | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- PIEZO2 | c.7370A>G p.Q2457R | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PIP4K2B | c.256_257+23del p.X86_splice | Splice Site (DEL) | VAF 20/216 reads (9%) | called by mutect2, pindel
- PKHD1L1 | c.1345G>C p.D449H | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.958); called by muse, mutect2
- PLCL1 | c.2595G>T p.M865I | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- PLXNB3 | c.3029G>T p.R1010L | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2
- PRDM9 | c.1588G>T p.G530* | Nonsense Mutation (SNP) | VAF 44/750 reads (6%) | called by muse, mutect2
- PTPRQ | c.2192C>A p.P731H (on ENST00000616559; = p.P689H on NM_001145026.2) | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM10 | c.1950G>T p.Q650H | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2
- RGL1 | c.2065G>T p.D689Y (on ENST00000360851 / NM_001297672.2; = p.D724Y on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2
- RGS7 | c.1146G>C p.Q382H | Missense Mutation (SNP) | VAF 18/339 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.794); called by muse, mutect2
- RYR2 | c.5953G>T p.E1985* | Nonsense Mutation (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- SALL3 | c.3032G>T p.R1011M | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); called by muse, mutect2
- SAMD9 | c.3626A>C p.Q1209P | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.4); called by muse, mutect2
- SH3KBP1 | c.646G>T p.G216* | Nonsense Mutation (SNP) | VAF 31/661 reads (5%) | called by muse, mutect2
- SLC17A3 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC25A46 | c.1097A>G p.Y366C | Missense Mutation (SNP) | VAF 38/446 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC39A13 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 45/551 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC4A9 | c.727G>A p.A243T (on ENST00000507527 / NM_001258428.2; = p.A219T on NM_031467.3) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2
- SLITRK4 | c.752G>T p.R251M | Missense Mutation (SNP) | VAF 51/584 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- SNTG2 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 15/368 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.037); called by muse, mutect2
- SORCS1 | c.2052C>A p.H684Q | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.929); called by muse, mutect2
- SOWAHD | c.530G>T p.R177M | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); called by muse, mutect2
- SRCAP | c.8193G>C p.R2731S | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2
- STAG2 | c.2609_2610insT p.K870Nfs*25 | Frame Shift Ins (INS) | VAF 22/201 reads (11%) | called by mutect2, pindel, varscan2
- SULF2 | c.2086T>C p.W696R | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); called by muse, varscan2
- TAF4 | c.2657G>T p.G886V | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- TLE4 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.759); called by muse, mutect2
- TMEM38B | c.14G>T p.W5L | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRIM2 | c.826C>A p.Q276K (on ENST00000437508; = p.Q303K on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2
- TRIM64C | c.794C>A p.P265Q | Missense Mutation (SNP) | VAF 24/513 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- UNC79 | c.1501A>T p.S501C (on ENST00000393151 / NM_001346218.2; = p.S324C on NM_020818.5) | Missense Mutation (SNP) | VAF 30/485 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- UNC80 | c.5937G>C p.K1979N | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- VGLL3 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.075); called by muse, mutect2
- VPS13A | c.3076A>G p.T1026A | Missense Mutation (SNP) | VAF 40/429 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- WDR35 | c.2164T>G p.C722G (on ENST00000345530 / NM_001006657.2; = p.C711G on NM_020779.4) | Missense Mutation (SNP) | VAF 54/582 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- XK | c.594G>T p.E198D | Missense Mutation (SNP) | VAF 18/293 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- ZBTB33 | c.1637G>A p.G546E | Missense Mutation (SNP) | VAF 50/451 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFP30 | c.331A>G p.S111G | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF285 | c.1324C>A p.H442N | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.887); called by muse, mutect2
- ZNF418 | c.1551G>T p.K517N | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF43 | c.338A>T p.H113L | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.034); called by muse, mutect2
- ZNF716 | c.888C>A p.Y296* | Nonsense Mutation (SNP) | VAF 36/464 reads (8%) | called by muse, mutect2
- ZP1 | c.912C>G p.N304K | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.388); called by muse, mutect2
- ALDH2 | c.384C>T p.G128= | Silent (SNP) | VAF 14/326 reads (4%) | called by muse, mutect2
- AMOTL2 | c.1476G>T p.A492= | Silent (SNP) | VAF 27/278 reads (10%) | catalogued as rs569708164; called by muse, mutect2
- AOC2 | c.615G>T p.V205= | Silent (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- CACNA1C | c.1827G>A p.K609= | Silent (SNP) | VAF 10/248 reads (4%) | catalogued as COSV59755600; called by muse, mutect2
- CAPN11 | c.2049C>A p.V683= | Silent (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- CDS2 | c.1041G>T p.S347= | Silent (SNP) | VAF 54/600 reads (9%) | catalogued as COSV66897004; called by muse, mutect2
- CHD8 | c.5328A>T p.R1776= (on ENST00000646647 / NM_001170629.2; = p.R1497= on NM_020920.4) | Silent (SNP) | VAF 34/361 reads (9%) | called by muse, mutect2
- CNTNAP5 | c.465G>T p.V155= | Silent (SNP) | VAF 28/289 reads (10%) | catalogued as COSV70494670; called by muse, mutect2, varscan2
- CYP17A1 | c.144T>C p.H48= | Silent (SNP) | VAF 36/376 reads (10%) | called by muse, mutect2
- CYP2C18 | c.399T>C p.N133= | Silent (SNP) | VAF 25/469 reads (5%) | catalogued as rs769770938; called by muse, mutect2
- DENND5B | c.2400G>T p.S800= | Silent (SNP) | VAF 16/259 reads (6%) | called by muse, mutect2
- EGLN2 | c.171C>T p.A57= | Silent (SNP) | VAF 11/143 reads (8%) | called by muse, mutect2
- FRMPD4 | c.2289G>T p.G763= | Silent (SNP) | VAF 15/222 reads (7%) | called by muse, mutect2
- GABRA5 | c.1167G>T p.P389= | Silent (SNP) | VAF 29/424 reads (7%) | catalogued as rs776414656, COSV59482736; called by muse, mutect2
- GAREM2 | c.1344C>G p.L448= | Silent (SNP) | VAF 26/278 reads (9%) | called by muse, mutect2
- GSDME | c.324C>T p.R108= | Silent (SNP) | VAF 18/342 reads (5%) | catalogued as rs376703607; called by muse, mutect2
- HCFC1 | c.91C>A p.R31= | Silent (SNP) | VAF 27/311 reads (9%) | called by muse, mutect2
- KCNS2 | c.1047C>G p.T349= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV54637816, COSV54641364; called by muse, mutect2
- KIF14 | c.3708C>T p.S1236= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as rs1343858920; called by muse, mutect2, varscan2
- L1CAM | c.3021G>A p.R1007= | Silent (SNP) | VAF 26/370 reads (7%) | catalogued as COSV100649120; called by muse, mutect2
- LPCAT1 | c.1521G>C p.A507= | Silent (SNP) | VAF 28/390 reads (7%) | called by muse, mutect2
- LVRN | c.2373G>T p.A791= | Silent (SNP) | VAF 20/182 reads (11%) | catalogued as rs763520683, COSV63496414; called by muse, mutect2, varscan2
- MCM6 | c.846A>T p.R282= | Silent (SNP) | VAF 21/330 reads (6%) | called by muse, mutect2
- MRPS31 | c.675G>T p.R225= | Silent (SNP) | VAF 20/276 reads (7%) | called by muse, mutect2
- MYT1L | c.2367C>A p.T789= | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as COSV67718258; called by muse, mutect2
- NRXN1 | c.2337G>C p.T779= | Silent (SNP) | VAF 22/200 reads (11%) | catalogued as rs202231291, COSV100456554, COSV58437958; called by muse, varscan2
- NXPE3 | c.786C>T p.T262= | Silent (SNP) | VAF 13/153 reads (8%) | catalogued as rs868341034; called by muse, mutect2
- OR4D11 | c.60C>A p.S20= | Silent (SNP) | VAF 9/106 reads (8%) | called by muse, mutect2
- OR52J3 | c.126G>T p.L42= | Silent (SNP) | VAF 36/644 reads (6%) | called by muse, mutect2
- PCDH8 | c.2259C>T p.I753= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- PXDN | c.4257G>T p.G1419= | Silent (SNP) | VAF 52/488 reads (11%) | called by muse, mutect2, varscan2
- RBP3 | c.1851G>T p.V617= | Silent (SNP) | VAF 12/326 reads (4%) | called by muse, mutect2
- RFX2 | c.417C>T p.V139= | Silent (SNP) | VAF 11/204 reads (5%) | catalogued as COSV57939129; called by muse, mutect2
- SEMA4C | c.903C>T p.H301= | Silent (SNP) | VAF 16/204 reads (8%) | catalogued as rs1404718644; called by muse, mutect2
- SLC39A12 | c.226C>A p.R76= | Silent (SNP) | VAF 20/284 reads (7%) | catalogued as COSV101069997; called by muse, mutect2
- SLC39A13 | c.456G>T p.G152= | Silent (SNP) | VAF 47/559 reads (8%) | called by muse, mutect2
- SLC9C2 | c.492T>A p.P164= | Silent (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2, varscan2
- TCEAL5 | c.348A>G p.A116= | Silent (SNP) | VAF 24/332 reads (7%) | called by muse, mutect2
- TLR10 | c.1068C>T p.A356= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV58299136; called by muse, mutect2, varscan2
- WDR35 | c.2163C>A p.R721= (on ENST00000345530 / NM_001006657.2; = p.R710= on NM_020779.4) | Silent (SNP) | VAF 57/573 reads (10%) | called by muse, mutect2
- XIRP2 | c.5055A>G p.T1685= (on ENST00000628543; = p.T1860= on NM_152381.6) | Silent (SNP) | VAF 24/320 reads (8%) | called by muse, mutect2
- ZHX3 | c.2517A>T p.L839= | Silent (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2
- ABI3BP | c.1576+6802T>C | Intron (SNP) | VAF 42/622 reads (7%) | called by muse, mutect2
- AF121898.1 | n.205+26787T>C | Intron (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- ARMC5 | c.1864+217G>C | Intron (SNP) | VAF 9/129 reads (7%) | called by muse, mutect2
- BCORL1 | c.4306-2712G>T | Intron (SNP) | VAF 18/360 reads (5%) | called by muse, mutect2
- EEFSEC | c.316+9G>T | Intron (SNP) | VAF 15/200 reads (8%) | called by muse, mutect2
- EMP1 | c.-12A>G | 5'UTR (SNP) | VAF 26/402 reads (6%) | called by muse, mutect2
- GABRB3 | c.*3G>T | 3'UTR (SNP) | VAF 19/254 reads (7%) | called by muse, mutect2
- GP2 | chr16:20327646 G>T | 5'Flank (SNP) | VAF 26/458 reads (6%) | catalogued as rs185291517; called by muse, mutect2
- IL20RB | c.89-94G>A | Intron (SNP) | VAF 10/147 reads (7%) | catalogued as rs757839951, COSV59047398, COSV59048159; called by muse, mutect2
- IRF2 | c.529+961C>T | Intron (SNP) | VAF 22/512 reads (4%) | catalogued as rs1434851150; called by muse, mutect2
- KLC2 | c.1785+179G>T | Intron (SNP) | VAF 20/140 reads (14%) | called by muse, mutect2
- MGAM | c.4618+11296G>T | Intron (SNP) | VAF 32/216 reads (15%) | called by muse, mutect2, varscan2
- MYH16 | n.2443C>A | RNA (SNP) | VAF 28/340 reads (8%) | called by muse, mutect2
- OLFM1 | chr9:135087345 G>T | 5'Flank (SNP) | VAF 12/158 reads (8%) | catalogued as rs1051398757; called by muse, mutect2
- PCNX1 | c.3466+28A>T | Intron (SNP) | VAF 4/95 reads (4%) | catalogued as rs1441532961; called by muse, mutect2
- PNCK | c.*271G>T | 3'UTR (SNP) | VAF 34/288 reads (12%) | called by muse, mutect2, varscan2
- PPP1R42 | c.*59G>A | 3'UTR (SNP) | VAF 15/184 reads (8%) | called by muse, mutect2
- PRKN | c.*12G>T | 3'UTR (SNP) | VAF 38/422 reads (9%) | catalogued as rs1483639679, COSV100630533; called by muse, mutect2
- PSG9 | c.1243+39G>T | Intron (SNP) | VAF 34/400 reads (9%) | called by muse, mutect2
- PTPRR | c.1498-10289C>G | Intron (SNP) | VAF 26/404 reads (6%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34158855 G>T | 5'Flank (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159650 C>A | 5'Flank (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- SLC43A2 | c.1217+201A>T | Intron (SNP) | VAF 10/123 reads (8%) | called by muse, mutect2
- ST3GAL3 | c.347+39G>A | Intron (SNP) | VAF 26/436 reads (6%) | called by muse, mutect2
- SYT14 | c.*447T>C | 3'UTR (SNP) | VAF 12/225 reads (5%) | called by muse, mutect2
- SYT14 | chr1:210162675 C>A | 3'Flank (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- TRIM29 | c.1334-168T>A | Intron (SNP) | VAF 35/399 reads (9%) | called by muse, mutect2
- TSEN34 | c.-131G>T | 5'UTR (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- UBTFL2 | n.849C>A | RNA (SNP) | VAF 50/1033 reads (5%) | catalogued as rs1436198327; called by muse, mutect2
- XIAP | c.*716del | 3'UTR (DEL) | VAF 7/59 reads (12%) | called by mutect2, pindel, varscan2
